Somatic mutation profile of tumor specimen TCGA-HU-A4H3-01A (aliquot TCGA-HU-A4H3-01A-21D-A25D-08) from TCGA case TCGA-HU-A4H3, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,790 days).
Specimen TCGA-HU-A4H3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0e7926b-dab2-4c56-bf3d-743189d97b72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4H3-10A (Blood Derived Normal), aliquot TCGA-HU-A4H3-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d90eef55-ae07-4be7-9ba6-633e5c19cc9b

The open-access MAF lists 1,110 somatic variants for this specimen: 844 protein-altering or splice-affecting, 234 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 521, Silent 234, Frame Shift Del 217, Frame Shift Ins 41, Nonsense Mutation 25, Splice Site 15, In Frame Del 15, Intron 12, Splice Region 9, 5'Flank 6, 3'UTR 5, RNA 5.

Variants (750 of 1,110; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs200771970, CM118332, COSV50035467; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CASR | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as rs1559959758, CM124146, COSV56136763; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- GNPTAB | c.2693dup p.Y899Vfs*21 | Frame Shift Ins (INS) | VAF 39/136 reads (29%) | catalogued as rs281864999; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KCNMA1 | c.2026del p.Y676Tfs*15 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | catalogued as rs762705295; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 44/146 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, varscan2
- MAN2B1 | c.2402del p.G801Afs*4 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs797044680, CM051105; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MKRN3 | c.482dup p.A162Gfs*15 | Frame Shift Ins (INS) | VAF 16/55 reads (29%) | catalogued as rs763195944; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC22A5 | c.844del p.R282Dfs*14 | Frame Shift Del (DEL) | VAF 73/238 reads (31%) | catalogued as rs386134209, CM045438; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SOX9 | c.1418A>G p.Q473R | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.968); catalogued as rs1064796718, COSV55423830; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 15/20 reads (75%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AAAS | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV52932765; called by muse, mutect2, varscan2
- ABCA13 | c.3762G>T p.E1254D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV70027573; called by muse, mutect2, varscan2
- ABCC8 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV56849376; called by muse, mutect2, varscan2
- ABCF3 | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs113949696, COSV53052123; called by muse, mutect2, varscan2
- ABCG1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV59203249; called by muse, mutect2, varscan2
- ABHD4 | c.506T>C p.V169A | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.177); catalogued as COSV53529614; called by muse, mutect2, varscan2
- AC126283.2 | c.111del p.K37Nfs*65 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | catalogued as rs1560546604; called by mutect2, pindel, varscan2
- ACCS | c.556+1del | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | catalogued as rs1207790264; called by mutect2, pindel, varscan2
- ACHE | c.1553+1G>A p.X518_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | catalogued as COSV53816964; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACSL4 | c.1868T>C p.L623S (on ENST00000340800 / NM_022977.2; = p.L582S on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100538559, COSV61615408; called by muse, mutect2, varscan2
- ACTN4 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV53145261; called by muse, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 57/86 reads (66%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS15 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV54504931; called by muse, mutect2, varscan2
- ADAMTSL1 | c.153del p.A53Pfs*5 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as COSV52807684; called by mutect2, varscan2
- ADAMTSL1 | c.2798A>G p.K933R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV65891658; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3815A>G p.D1272G | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54445121; called by muse, mutect2, varscan2
- ADCY10 | c.4816G>A p.V1606M | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs201892899; called by muse, mutect2, varscan2
- ADCY9 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as rs143296765, COSV53574351; called by muse, mutect2, varscan2
- ADGRG1 | c.843del p.S281Rfs*42 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as COSV65636865; called by mutect2, varscan2
- ADGRV1 | c.3994G>A p.G1332R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775914750, COSV101315511, COSV67983679; called by muse, mutect2, varscan2
- AFM | c.1647-1G>T p.X549_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV56919836; called by muse, mutect2, varscan2
- AGO4 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs773809553, COSV64616987; called by muse, mutect2, varscan2
- AHCTF1 | c.3773C>T p.P1258L (on ENST00000366508; = p.P1232L on NM_015446.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58245518; called by muse, mutect2, varscan2
- AHCYL1 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); catalogued as COSV63208534; called by muse, mutect2, varscan2
- AJUBA | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV52984999; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as COSV62339755; called by mutect2, varscan2
- AL162417.1 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV64404374; called by muse, mutect2, varscan2
- ALDH3B1 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs755218225; called by muse, mutect2, varscan2
- ALDOB | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV66397712; called by muse, mutect2, varscan2
- ALG12 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | PolyPhen benign (0.037); catalogued as rs755033821, COSV58206797; called by muse, mutect2, varscan2
- ALKBH1 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs370283555; called by muse, mutect2, varscan2
- ALOX12B | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs1209666298, COSV59872343; called by muse, mutect2, varscan2
- ALPK3 | c.2304dup p.P769Tfs*8 | Frame Shift Ins (INS) | VAF 55/145 reads (38%) | catalogued as rs1351644582; called by mutect2, varscan2
- ALPK3 | c.3025C>T p.R1009W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs765812547, COSV51932621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPP | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760691687, COSV101235146; called by muse, mutect2, varscan2
- AMHR2 | c.800del p.G267Vfs*25 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs748387033; called by mutect2, pindel, varscan2
- AMN | c.385_387del p.F129del | In Frame Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1434846488; called by pindel, varscan2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | catalogued as rs1319526303; called by mutect2, pindel, varscan2
- AMPH | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV57740032; called by muse, mutect2, varscan2
- ANKRD46 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV59514126; called by muse, mutect2, varscan2
- ANKS1A | c.959del p.P320Hfs*25 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as COSV64461548; called by mutect2, pindel, varscan2
- ANKS1B | c.1514A>G p.D505G | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs371186191; called by muse, mutect2, varscan2
- ANKS6 | c.2317A>G p.T773A | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62049999; called by muse, mutect2, varscan2
- ANO8 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.18); catalogued as COSV50175799; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 54/208 reads (26%) | catalogued as rs759218332; called by mutect2, varscan2
- APC | c.4918C>T p.R1640W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs373440614, CM942083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLP2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765345417, COSV53840461; called by muse, mutect2, varscan2
- AQP12B | c.326G>A p.G109D (on ENST00000621682; = p.G121D on NM_001102467.2) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68183894, COSV68184440; called by muse, mutect2, varscan2
- ARF4 | c.64A>G p.M22V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV57714920; called by muse, mutect2, varscan2
- ARHGEF10 | c.1879G>A p.E627K (on ENST00000398564; = p.E602K on NM_014629.4) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs556107310, COSV50646939; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 32/121 reads (26%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARMC4 | c.1532A>G p.K511R | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV59462050; called by muse, mutect2, varscan2
- ARMC9 | c.1007T>C p.L336S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63020518; called by muse, mutect2, varscan2
- ARMH4 | c.1708del p.E570Nfs*99 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | catalogued as COSV50777149; called by mutect2, pindel, varscan2
- ARRDC1 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.339); catalogued as COSV58374148; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs753865255; called by mutect2, varscan2
- ASH1L | c.6568G>C p.E2190Q (on ENST00000368346 / NM_001366177.2; = p.E2185Q on NM_018489.3) | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as COSV64207354; called by muse, mutect2
- ASPM | c.8644T>C p.Y2882H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as rs201732387, COSV54128623; called by muse, mutect2, varscan2
- ASTN1 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.054); catalogued as COSV56066938; called by muse, mutect2, varscan2
- ATAD2 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1217927979, COSV54879991; called by muse, mutect2, varscan2
- ATAD2 | c.792T>A p.D264E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149848860; called by muse, varscan2
- ATG13 | c.1473C>G p.D491E (on ENST00000359513 / NM_001346321.1; = p.D454E on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV56318969; called by muse, mutect2, varscan2
- ATG9B | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs1167535525, COSV52502619, COSV99873717; called by muse, mutect2, varscan2
- ATP1A3 | c.365C>T p.A122V (on ENST00000545399 / NM_001256214.2; = p.A109V on NM_152296.5) | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1568866568, COSV57486973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP9A | c.1328C>T p.T443M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.505); catalogued as rs756196040, COSV58765482; called by muse, mutect2, varscan2
- AVIL | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922509093, COSV57681528; called by muse, mutect2, varscan2
- B3GALNT2 | c.1421_1423del p.P474del | In Frame Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs752758430; called by pindel, varscan2
- B3GALT4 | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65851497; called by muse, mutect2, varscan2
- BACH2 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57590379, COSV99999884; called by muse, mutect2, varscan2
- BAZ2B | c.6145C>T p.Q2049* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV58599347; called by muse, mutect2, varscan2
- BBS9 | c.2273C>T p.P758L (on ENST00000242067 / NM_001348036.1; = p.P718L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757754301, COSV54165316, COSV54173388; called by muse, mutect2, varscan2
- BCAS1 | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.104); catalogued as COSV65085397; called by muse, mutect2, varscan2
- BCAT2 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs773005638, COSV60272326; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs752427670; called by mutect2, varscan2
- BDP1 | c.4837A>T p.T1613S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV62430874; called by muse, mutect2
- BET1L | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373427261, COSV57316017; called by muse, mutect2, varscan2
- BMP8A | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs765056618, COSV59032663; called by muse, mutect2, varscan2
- BMPR1B | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1471363374, COSV52776601; called by muse, mutect2, varscan2
- BMT2 | c.906T>A p.F302L | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.853); catalogued as COSV51776181; called by muse, mutect2, varscan2
- BRD2 | c.2081C>A p.S694Y | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66373038; called by muse, mutect2, varscan2
- BSN | c.4523C>T p.T1508M | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768423977, COSV56516507; called by muse, mutect2, varscan2
- C19orf44 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV55611795; called by muse, mutect2, varscan2
- C1QL1 | c.407T>G p.L136R | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV53646940; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | catalogued as rs781818365; called by mutect2, pindel, varscan2
- C4orf19 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as COSV52649207; called by muse, mutect2, varscan2
- C6orf47 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs765482502, COSV63263742; called by muse, mutect2, varscan2
- CAMKV | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as COSV56555054; called by muse, mutect2, varscan2
- CAND2 | c.3140G>A p.R1047Q (on ENST00000456430 / NM_001162499.2; = p.R930Q on NM_012298.3) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1261227314, COSV55989103; called by muse, mutect2, varscan2
- CASD1 | c.542T>C p.L181P | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51972049; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs765105588; called by mutect2, varscan2
- CATSPERG | c.1523T>G p.L508R | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53048088; called by muse, mutect2, varscan2
- CBX1 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 29/105 reads (28%) | catalogued as COSV56681749, COSV56682056; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 59/245 reads (24%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC120 | c.1390del p.E464Sfs*170 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as COSV64481542; called by mutect2, pindel, varscan2
- CCDC17 | c.1598A>G p.Q533R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59646840; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC197 | c.321C>A p.H107Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as COSV100113649; called by muse, mutect2, varscan2
- CCDC40 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs371890970, COSV53903999; called by muse, mutect2
- CCDC88A | c.2524C>T p.R842* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as COSV55060320; called by muse, mutect2, varscan2
- CCDC96 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs868326302, COSV59508539; called by muse, mutect2, varscan2
- CCDC97 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs747366546, COSV54190082; called by muse, mutect2, varscan2
- CCR3 | c.701del p.K234Sfs*52 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | catalogued as rs761073142; called by mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD93 | c.838del p.D280Mfs*19 | Frame Shift Del (DEL) | VAF 42/160 reads (26%) | catalogued as rs1276928429, COSV55666935; called by mutect2, varscan2
- CDC42EP1 | c.289del p.R97Gfs*115 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs762035931; called by mutect2, pindel, varscan2
- CDCP1 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56104889; called by muse, mutect2, varscan2
- CDH16 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV55335750; called by muse, mutect2, varscan2
- CDH4 | c.1627A>C p.R543= | Splice Region (SNP) | VAF 13/35 reads (37%) | catalogued as COSV64651210; called by muse, mutect2, varscan2
- CDHR2 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs746333783, COSV56135002, COSV56137768; called by muse, mutect2, varscan2
- CDK15 | c.40T>C p.C14R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV53633639; called by muse, mutect2, varscan2
- CDS2 | c.977G>A p.G326D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as COSV66896197; called by muse, mutect2, varscan2
- CELSR3 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50850078; called by muse, mutect2, varscan2
- CENPE | c.4909A>G p.N1637D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as COSV54380118; called by muse, mutect2, varscan2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP78 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781363287, COSV52846874; called by muse, mutect2, varscan2
- CEP95 | c.1236T>G p.D412E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV73609028; called by muse, mutect2, varscan2
- CFAP251 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV56609774; called by muse, mutect2, varscan2
- CFAP43 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs753365408, COSV53376338; called by muse, mutect2, varscan2
- CFAP97 | c.307T>A p.L103M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV57110184; called by muse, mutect2, varscan2
- CHAC2 | c.171G>T p.A57= | Splice Region (SNP) | VAF 17/88 reads (19%) | catalogued as COSV54857913; called by muse, mutect2, varscan2
- CHRNB4 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV55715726; called by muse, mutect2, varscan2
- CIB2 | c.249G>T p.E83D | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51948272, COSV51949951; called by muse, mutect2, varscan2
- CLCN2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149439531; called by muse, mutect2, varscan2
- CLDN12 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55306729; called by muse, mutect2, varscan2
- CMYA5 | c.7358C>T p.P2453L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.794); catalogued as COSV71405504; called by muse, mutect2, varscan2
- CNBD2 | c.1306G>A p.D436N (on ENST00000373973 / NM_001365709.1; = p.D432N on NM_080834.4) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs748255965, COSV100839098; called by muse, mutect2, varscan2
- CNNM3 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV59709085; called by muse, mutect2, varscan2
- CNST | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs370560810; called by muse, mutect2, varscan2
- CNTN5 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563536789, COSV54292791, COSV54313614, COSV54314691; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 38/58 reads (66%) | catalogued as rs374805044; called by mutect2, varscan2
- COL5A3 | c.4317T>C p.G1439= | Splice Region (SNP) | VAF 23/70 reads (33%) | catalogued as COSV53409612; called by muse, mutect2, varscan2
- COL6A1 | c.1740G>T p.Q580H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.188); catalogued as COSV62612787; called by muse, mutect2
- COQ8A | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1558208407, COSV64657171; called by muse, mutect2, varscan2
- CORIN | c.1858_1859dup p.D620Efs*13 | Frame Shift Ins (INS) | VAF 29/94 reads (31%) | catalogued as rs773653221; called by mutect2, varscan2
- CPXM2 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs762600262, COSV53860503; called by muse, mutect2, varscan2
- CRHR1 | c.568G>A p.A190T (on ENST00000398285 / NM_001145146.2; = p.A161T on NM_004382.5) | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.094); catalogued as rs767597712, COSV53277026; called by muse, mutect2, varscan2
- CRTC3 | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51596083; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 34/115 reads (30%) | catalogued as rs762650691; called by mutect2, varscan2
- CSMD1 | c.3077A>G p.D1026G (on ENST00000520002; = p.D1025G on NM_033225.6) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59312883; called by muse, mutect2, varscan2
- CSMD3 | c.8429C>T p.T2810I (on ENST00000297405 / NM_001363185.1; = p.T2641I on NM_052900.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.88); catalogued as COSV52159788, COSV52252067; called by muse, mutect2, varscan2
- CSMD3 | c.4886C>T p.A1629V (on ENST00000297405 / NM_001363185.1; = p.A1525V on NM_052900.3) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.611); catalogued as rs778050124, COSV52159807; called by muse, varscan2
- CST7 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs774561103, COSV65195674; called by muse, mutect2, varscan2
- CTNNA1 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs973328870, COSV57073039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL7 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54815778; called by muse, mutect2, varscan2
- CUL9 | c.7460A>G p.N2487S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV52727785; called by muse, mutect2, varscan2
- CXCL10 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs1268319416, COSV60660932; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 29/125 reads (23%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYFIP2 | c.1978A>G p.I660V (on ENST00000616178 / NM_001291722.2; = p.I635V on NM_014376.4) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV59035078; called by muse, mutect2, varscan2
- CYP1A1 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs371074476, COSV65696914, COSV65696988; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs751187768; called by mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DBN1 | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.011); catalogued as COSV52789180; called by muse, mutect2, varscan2
- DCAF11 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58108932; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 42/104 reads (40%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX59 | c.542A>C p.Q181P | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58751648; called by muse, mutect2, varscan2
- DGCR8 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV52813172; called by muse, mutect2, varscan2
- DHRS9 | c.669del p.K223Nfs*25 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs756920263; called by mutect2, varscan2
- DHX35 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs1243578098, COSV52669620; called by muse, mutect2, varscan2
- DIDO1 | c.6161C>T p.A2054V | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56620013; called by muse, mutect2, varscan2
- DIPK2B | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV67641067; called by muse, mutect2, varscan2
- DIS3 | c.542_543del p.K181Rfs*14 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs1197150249; called by mutect2, pindel, varscan2
- DLEC1 | c.4969G>A p.V1657I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.084); catalogued as COSV57173353; called by muse, mutect2, varscan2
- DMD | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as CM096423, COSV55866458; called by muse, mutect2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF6 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1175590526, COSV60495681; called by muse, mutect2, varscan2
- DNAH8 | c.12143C>T p.P4048L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs371913220; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC10 | c.1178del p.N393Mfs*28 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as COSV51144125, COSV51147329; called by mutect2, pindel
- DNAJC5B | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV52537071; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.4402C>T p.R1468* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs752179590, COSV53913678; called by muse, mutect2, varscan2
- DPCD | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as rs1322677277, COSV64509222; called by muse, mutect2, varscan2
- DROSHA | c.3887G>A p.R1296Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60775062; called by muse, mutect2, varscan2
- DROSHA | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV60775078; called by muse, mutect2, varscan2
- DSP | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs368778031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.4208G>T p.R1403M | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV65792411, COSV65795830; called by muse, mutect2, varscan2
- DTX4 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs200498275; called by muse, mutect2, varscan2
- DTX4 | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57090020; called by muse, mutect2, varscan2
- DVL3 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs778117558, COSV57455780; called by muse, mutect2, varscan2
- DYNC1LI1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56127322; called by muse, mutect2, varscan2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- ECT2 | c.2024G>A p.R675Q (on ENST00000392692 / NM_001349098.2; = p.R644Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as rs146823982; called by muse, mutect2, varscan2
- EDA2R | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV53631068; called by muse, mutect2
- EEFSEC | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs762292921, COSV54624544; called by muse, mutect2, varscan2
- EFHD1 | c.376del p.Q126Rfs*6 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | catalogued as rs760712775, COSV51135066; called by mutect2, pindel, varscan2
- EHD2 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767063664, COSV54406532; called by muse, mutect2, varscan2
- EIF2B4 | c.331G>A p.E111K (on ENST00000347454 / NM_001034116.2; = p.E110K on NM_015636.3) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as rs760388895, COSV52007429; called by muse, mutect2, varscan2
- EIF2S1 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56452218; called by muse, mutect2, varscan2
- EIF4G2 | c.1313T>A p.L438H | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60596911; called by muse, mutect2, varscan2
- ELAC2 | c.2099A>C p.K700T | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52393169; called by muse, mutect2
- EML5 | c.2819C>T p.A940V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV61344679; called by muse, mutect2, varscan2
- EN1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.108); catalogued as COSV54630863, COSV99727391; called by muse, mutect2
- ENG | c.461del p.G154Afs*9 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | catalogued as CD040889; called by mutect2, pindel, varscan2
- ENKUR | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV58632981; called by muse, mutect2, varscan2
- ENOX1 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.613); catalogued as rs761977987, COSV54896563; called by muse, mutect2, varscan2
- EP400 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs764793090, COSV100201239; called by muse, mutect2, varscan2
- EPHA6 | c.1075T>C p.C359R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV67569460; called by muse, mutect2, varscan2
- EPS8L3 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62609282; called by muse, mutect2, varscan2
- ESRP1 | c.1667C>T p.S556F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.62); catalogued as COSV64409172; called by muse, mutect2, varscan2
- EXTL3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as COSV55037723; called by muse, mutect2, varscan2
- EXTL3 | c.2720G>A p.R907H | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55037729; called by muse, mutect2, varscan2
- FAM107B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); catalogued as COSV51683106, COSV51692349; called by muse, mutect2, varscan2
- FAM126A | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV69471534; called by muse, mutect2, varscan2
- FAM133A | c.662A>T p.K221I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.994); catalogued as COSV59074924; called by muse, mutect2, varscan2
- FAM151A | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as rs1395826909, COSV56363763; called by muse, mutect2, varscan2
- FAM155A | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV65558926; called by muse, mutect2, varscan2
- FAM184A | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1419377549, COSV58853672; called by muse, mutect2, varscan2
- FAM47C | c.1797del p.E600Rfs*225 | Frame Shift Del (DEL) | VAF 36/140 reads (26%) | catalogued as rs1556332794; called by pindel, varscan2
- FASN | c.3484C>T p.P1162S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs1452692285, COSV60753387; called by muse, mutect2, varscan2
- FASTKD1 | c.10dup p.T4Nfs*34 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs771228336; called by mutect2, varscan2
- FBXL7 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV61644846; called by muse, mutect2, varscan2
- FBXO25 | c.199del p.R67Gfs*44 (on ENST00000382824 / NM_183421.2; = p.G17Efs*6 on NM_012173.3) | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as rs758426962; called by mutect2, pindel, varscan2
- FBXO47 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759147995, COSV65241637; called by muse, mutect2, varscan2
- FGF10 | c.235T>G p.W79G | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.093); catalogued as COSV52933798; called by muse, mutect2, varscan2
- FICD | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV57206836; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLNA | c.5146del p.Q1716Sfs*23 (on ENST00000369850 / NM_001110556.2; = p.Q1708Sfs*23 on NM_001456.3) | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | catalogued as COSV61048769; called by mutect2, pindel, varscan2
- FLNB | c.3466G>A p.V1156I | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); catalogued as rs771189591, COSV55877416, COSV55892189; called by muse, mutect2, varscan2
- FLNC | c.6451G>A p.G2151S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1413293, COSV57954624; called by muse, mutect2, varscan2
- FLRT2 | c.1750C>T p.R584W | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1248212249, COSV58136841; called by muse, mutect2, varscan2
- FLT3 | c.2882G>C p.R961P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV54050941; called by muse, mutect2, varscan2
- FN1 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs1224176023, COSV60551251; called by muse, mutect2, varscan2
- FN3K | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1457545883, COSV56181863; called by muse, mutect2, varscan2
- FOXD4 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV58699779; called by muse, varscan2
- FOXP1 | c.739A>G p.N247D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.045); catalogued as COSV59540630; called by muse, mutect2, varscan2
- FRMD7 | c.2067_2069del p.E689del | In Frame Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs745846839; called by pindel, varscan2
- FRMPD3 | c.2587C>A p.P863T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99346336; called by muse, mutect2, varscan2
- FSIP2 | c.19910del p.N6637Mfs*7 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV58081183; called by mutect2, pindel, varscan2
- FUBP1 | c.1907A>C p.Q636P | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.185); catalogued as COSV53929701; called by muse, mutect2, varscan2
- FYCO1 | c.4315C>T p.R1439C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779810632, COSV56113734; called by muse, mutect2, varscan2
- GALR2 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs569895534, COSV57162311; called by muse, mutect2, varscan2
- GBP6 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV65011275; called by muse, mutect2, varscan2
- GDF5 | c.498del p.I167Sfs*26 | Frame Shift Del (DEL) | VAF 37/124 reads (30%) | catalogued as CD016280; called by mutect2, pindel, varscan2
- GH2 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1366247658, COSV60426722; called by muse, mutect2, varscan2
- GHRHR | c.812+1G>A p.X271_splice | Splice Site (SNP) | VAF 53/96 reads (55%) | catalogued as rs770246828, CS096025, COSV58196255; called by muse, mutect2, varscan2
- GLG1 | c.2999G>A p.R1000H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs1421527712, COSV52666179; called by muse, mutect2, varscan2
- GLG1 | c.1501C>T p.R501* | Nonsense Mutation (SNP) | VAF 39/103 reads (38%) | catalogued as COSV52666190; called by muse, mutect2, varscan2
- GLI1 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV57360926, COSV57364769; called by muse, mutect2, varscan2
- GLI3 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.694); catalogued as COSV101230133, COSV67887651; called by muse, mutect2, varscan2
- GLIS2 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52110109; called by muse, mutect2, varscan2
- GLUD2 | c.1627A>G p.I543V | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV60151775; called by muse, mutect2, varscan2
- GM2A | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64095458; called by muse, mutect2, varscan2
- GON4L | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as COSV55192286; called by muse, mutect2, varscan2
- GRID2 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs550165966, COSV56188977; called by muse, mutect2, varscan2
- GRIN3A | c.2350A>G p.K784E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62452809; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | catalogued as rs747773579; called by mutect2, varscan2
- GTF3C2 | c.869A>G p.H290R | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.084); catalogued as COSV53126136; called by muse, mutect2, varscan2
- GTF3C5 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1362067951, COSV59599657; called by muse, mutect2, varscan2
- GYG2 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58549824; called by muse, mutect2, varscan2
- GYS1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54402427; called by muse, mutect2, varscan2
- HDAC4 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772767638, COSV61863838; called by muse, mutect2, varscan2
- HECTD4 | c.12113C>T p.S4038L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV66390569; called by muse, mutect2, varscan2
- HIP1 | c.1322G>T p.R441M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV61185195; called by muse, mutect2, varscan2
- HIVEP2 | c.2216G>T p.R739M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV50009429; called by muse, mutect2, varscan2
- HMGCLL1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.784); catalogued as rs1433675878, COSV51443884; called by muse, mutect2, varscan2
- HNRNPLL | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs759911825, COSV55366990; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1940del p.G647Efs*268 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as rs1451726686; called by mutect2, pindel, varscan2
- HPSE | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as COSV60986513; called by muse, mutect2, varscan2
- HRG | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs1039481155, COSV51645089; called by muse, mutect2
- HSP90AA1 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV53488341; called by muse, mutect2, varscan2
- HSPA12A | c.974T>G p.V325G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV65021944; called by muse, mutect2, varscan2
- HTR1E | c.801dup p.F268Lfs*4 | Frame Shift Ins (INS) | VAF 58/190 reads (31%) | catalogued as rs753568078; called by mutect2, varscan2
- HTR7 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53285702; called by muse, mutect2, varscan2
- HUNK | c.1502G>A p.R501H | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.469); catalogued as rs748171279, COSV54227411; called by muse, mutect2, varscan2
- HYDIN | c.15208C>T p.R5070W | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs577654275, COSV101125259, COSV66638558; called by muse, mutect2, varscan2
- ICAM5 | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1341637526, COSV55746992; called by muse, mutect2, varscan2
- ICE1 | c.5974G>A p.A1992T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763288159, COSV56823088; called by muse, mutect2, varscan2
- IFNGR1 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV62989743; called by muse, mutect2, varscan2
- IGSF1 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.813); catalogued as rs750429785, COSV100811925, COSV63837095; called by muse, mutect2, varscan2
- IGSF10 | c.602C>A p.P201H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56784335; called by muse, mutect2, varscan2
- IL12A | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); catalogued as COSV59759162; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1058-2A>C p.X353_splice | Splice Site (SNP) | VAF 71/186 reads (38%) | catalogued as COSV56254963; called by muse, mutect2, varscan2
- IL21R | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs767011874, COSV61969871; called by muse, mutect2
- IMPG2 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV51977031; called by muse, mutect2, varscan2
- INPP5B | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.712); catalogued as rs746857492, COSV65957780; called by muse, mutect2, varscan2
- INTS3 | c.2212C>A p.L738M | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV59676880; called by muse, mutect2, varscan2
- IQUB | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs111558568, COSV61238747; called by muse, mutect2, varscan2
- IRF2 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs865781754, COSV66928831; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 75/242 reads (31%) | catalogued as rs780982673; called by mutect2, varscan2
- ISOC1 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51491589; called by muse, mutect2, varscan2
- ITPR3 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65408272; called by muse, mutect2, varscan2
- IWS1 | c.1792C>T p.L598F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54867935; called by muse, varscan2
- JARID2 | c.1186dup p.A396Gfs*25 | Frame Shift Ins (INS) | VAF 30/109 reads (28%) | catalogued as rs778734711; called by mutect2, varscan2
- JARID2 | c.3733T>C p.S1245P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV59039569; called by muse, mutect2, varscan2
- JKAMP | c.343G>A p.A115T (on ENST00000554271 / NM_001284201.1; = p.A101T on NM_016475.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV54199157; called by muse, mutect2, varscan2
- KAT6A | c.1285del p.E429Kfs*49 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | catalogued as rs1564034388; called by mutect2, pindel, varscan2
- KAT6A | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55905354; called by muse, mutect2, varscan2
- KATNA1 | c.1361A>G p.H454R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV59502181; called by muse, mutect2, varscan2
- KATNB1 | c.1297C>T p.L433= | Splice Region (SNP) | VAF 15/51 reads (29%) | catalogued as COSV65549983; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | catalogued as rs754892524; called by mutect2, pindel, varscan2
- KCNJ3 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54535098; called by muse, mutect2, varscan2
- KCNS1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481433754, COSV60259992; called by muse, mutect2, varscan2
- KCNV1 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52085781; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KIAA1210 | c.2544A>C p.E848D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.909); catalogued as COSV68176779; called by muse, mutect2, varscan2
- KIF16B | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1218014015, COSV61705200, COSV61710672; called by muse, mutect2, varscan2
- KIF1B | c.3455C>T p.T1152M (on ENST00000377086 / NM_001365952.1; = p.T1106M on NM_015074.3) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs775773486, COSV55807680; called by muse, mutect2, varscan2
- KLRC2 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.093); catalogued as COSV101122698; called by muse, mutect2, varscan2
- KMT2B | c.3145del p.A1049Rfs*133 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as COSV55869560; called by mutect2, pindel, varscan2
- KMT2B | c.3511G>A p.V1171I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55857264; called by muse, mutect2
- KMT2B | c.4202G>A p.W1401* | Nonsense Mutation (SNP) | VAF 37/114 reads (32%) | catalogued as COSV55859938; called by muse, mutect2, varscan2
- KMT2B | c.7775A>G p.K2592R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV53074588; called by muse, mutect2, varscan2
- KMT2C | c.5792C>A p.S1931* | Nonsense Mutation (SNP) | VAF 88/155 reads (57%) | catalogued as COSV51431135; called by muse, mutect2, varscan2
- KMT2D | c.14890C>T p.R4964C | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs759822794, COSV56431296; called by muse, mutect2, varscan2
- KNSTRN | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51104814; called by muse, mutect2, varscan2
- KRT23 | c.119dup p.A41Sfs*76 | Frame Shift Ins (INS) | VAF 24/87 reads (28%) | catalogued as rs748265990; called by mutect2, pindel, varscan2
- KRT34 | c.1229C>A p.P410H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67449684; called by muse, mutect2, varscan2
- KRT35 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs777060154, COSV55842576; called by muse, mutect2
- KRTAP9-8 | c.161del p.N54Tfs*9 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as COSV54199592; called by mutect2, varscan2
- KSR1 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52038382, COSV99259555; called by muse, mutect2, varscan2
- LAMA1 | c.1138T>C p.Y380H | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV67535728; called by muse, mutect2
- LAMB3 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV61916464; called by muse, mutect2, varscan2
- LAMP1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs865825882, COSV60211440; called by muse, mutect2, varscan2
- LBR | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); catalogued as rs751127239, COSV55288613; ClinVar: uncertain significance; called by muse, varscan2
- LEMD2 | c.1383G>T p.W461C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53393727; called by muse, mutect2, varscan2
- LEPR | c.3477G>T p.K1159N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV62746025, COSV62746103; called by muse, mutect2, varscan2
- LGI3 | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60443248; called by muse, mutect2, varscan2
- LHFPL3 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV67810053; called by muse, mutect2, varscan2
- LILRA6 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768328589; called by muse, mutect2
- LILRB1 | c.896G>A p.R299H (on ENST00000427581; = p.R263H on NM_006669.6) | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs374212814; called by muse, mutect2
- LMNTD2 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.515); catalogued as COSV54240255; called by muse, mutect2, varscan2
- LMO3 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53782258; called by muse, mutect2
- LONP1 | c.1303A>G p.M435V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.165); catalogued as rs936754193, COSV62261438; called by muse, mutect2, varscan2
- LOXL2 | c.2276del p.K759Sfs*9 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs765428971; called by mutect2, pindel, varscan2
- LOXL2 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1212954688, COSV66691234; called by muse, mutect2, varscan2
- LRFN2 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as rs762597625, COSV57826466; called by muse, mutect2, varscan2
- LRFN3 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.363); catalogued as rs770775946, COSV55817470; called by muse, mutect2, varscan2
- LRFN5 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747782144, COSV53253065; called by muse, mutect2, varscan2
- LRFN5 | c.1529C>T p.T510M | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150445484; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 29/135 reads (21%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP1B | c.6482G>A p.R2161Q | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs200035883, COSV67209112; called by muse, mutect2, varscan2
- LRP4 | c.2610C>T p.G870= | Splice Region (SNP) | VAF 14/42 reads (33%) | catalogued as rs751431064, COSV66135397; called by muse, mutect2, varscan2
- LRRC15 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs180967725, COSV61649457; called by muse, mutect2, varscan2
- LRRC28 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 98/357 reads (27%) | catalogued as COSV57337583, COSV57342695; called by muse, mutect2, varscan2
- LRRFIP2 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1223979576, COSV60867259; called by muse, mutect2, varscan2
- LRRTM1 | c.141del p.R48Gfs*41 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as COSV99702656; called by mutect2, pindel, varscan2
- LSM14B | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.202); catalogued as COSV53380049; called by muse, mutect2, varscan2
- LTBP3 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1442604022, COSV57240023; called by muse, mutect2, varscan2
- LUM | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57127984; called by muse, mutect2, varscan2
- LURAP1 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64338124, COSV64338178; called by muse, mutect2, varscan2
- LYSMD3 | c.919_920del p.*307Afs*5 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs761158034; called by mutect2, pindel, varscan2
- LYZL1 | c.562A>G p.K188E (on ENST00000375500; = p.K142E on NM_032517.6) | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs753350610, COSV64966279; called by muse, mutect2, varscan2
- MAFB | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs776821286, COSV64826527; called by muse, mutect2, varscan2
- MAGEA1 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.211); catalogued as COSV63118470; called by muse, mutect2, varscan2
- MAGEB3 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV64396985; called by muse, mutect2, varscan2
- MAGEC1 | c.3184T>C p.S1062P | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.291); catalogued as COSV53571565; called by muse, varscan2
- MAGED1 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs781817508, COSV58514701; called by muse, mutect2
- MAMDC2 | c.776A>T p.N259I | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as COSV65857797; called by muse, mutect2, varscan2
- MAP3K15 | c.2804C>A p.P935H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV58828751; called by muse, mutect2, varscan2
- MAP4K2 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV53642469; called by mutect2, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 20/72 reads (28%) | catalogued as rs746267361; called by mutect2, varscan2
- MDN1 | c.3195C>G p.N1065K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV65520662; called by muse, mutect2, varscan2
- MED13L | c.3278A>G p.N1093S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56118866; called by muse, mutect2, varscan2
- MED16 | c.1817T>G p.L606R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs996870320, COSV54125677; called by muse, mutect2, varscan2
- MED26 | c.148-1G>A p.X50_splice | Splice Site (SNP) | VAF 25/65 reads (38%) | catalogued as COSV99659997; called by muse, mutect2, varscan2
- MEGF8 | c.2345G>T p.R782L (on ENST00000251268 / NM_001271938.2; = p.R715L on NM_001410.3) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1436403322, COSV52082190; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs745891632; called by mutect2, varscan2
- MET | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 81/168 reads (48%) | catalogued as COSV59260253; called by muse, mutect2, varscan2
- METAP1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs778153414, COSV56443228; called by muse, mutect2, varscan2
- METTL17 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59555834; called by muse, mutect2, varscan2
- MEX3B | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1279215915, COSV61663261; called by muse, mutect2, varscan2
- MFSD12 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as rs765464980, COSV61535274; called by muse, mutect2, varscan2
- MGAM | c.2733C>A p.S911R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV72074495, COSV72074785; called by mutect2, varscan2
- MGARP | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.218); catalogued as rs1406329699, COSV67449249; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MLXIP | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs756776307, COSV100039169, COSV59834782; called by muse, mutect2
- MMEL1 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750186428, COSV56520790; called by muse, mutect2, varscan2
- MMP10 | c.348-1G>T p.X116_splice | Splice Site (SNP) | VAF 27/105 reads (26%) | catalogued as COSV54246123; called by muse, mutect2, varscan2
- MMRN1 | c.2260A>G p.T754A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV53336651; called by muse, mutect2, varscan2
- MOGS | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV51968992; called by muse, mutect2, varscan2
- MORN5 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762113900, COSV65648618; called by muse, mutect2, varscan2
- MREG | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as rs764144154, COSV54373560; called by muse, mutect2, varscan2
- MROH5 | c.92del p.P31Lfs*6 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs748849454; called by mutect2, pindel, varscan2
- MTA1 | c.1913dup p.S639Lfs*18 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs1555433939; called by mutect2, varscan2
- MTNR1A | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56155717; called by muse, mutect2, varscan2
- MUC16 | c.31245A>C p.Q10415H | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV67461383; called by muse, mutect2, varscan2
- MUC16 | c.4016C>A p.S1339Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV67461384; called by muse, mutect2, varscan2
- MUC17 | c.7990G>A p.V2664M | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.861); catalogued as COSV60286428, COSV60296569; called by muse, mutect2
- MUC4 | c.13063C>T p.R4355C (on ENST00000463781 / NM_018406.7; = p.R119C on NM_004532.6) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs770422854, COSV57777523; called by muse, mutect2, varscan2
- MUC5B | c.13031C>A p.P4344H | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV71591584, COSV71596669; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 14/27 reads (52%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 30/114 reads (26%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- MYO15A | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV52755504; called by muse, mutect2, varscan2
- MYO15A | c.5776C>T p.R1926C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539637895, COSV52755516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18A | c.627del p.V210Wfs*86 | Frame Shift Del (DEL) | VAF 37/101 reads (37%) | catalogued as COSV62866672, COSV62872682; called by mutect2, pindel, varscan2
- MYO1G | c.514T>G p.F172V | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51854309; called by muse, mutect2, varscan2
- MYO3B | c.1231dup p.H411Pfs*51 | Frame Shift Ins (INS) | VAF 21/61 reads (34%) | catalogued as rs773041833; called by mutect2, varscan2
- MYORG | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.052); catalogued as rs986613484, COSV52627012; called by muse, mutect2, varscan2
- NAALADL1 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as rs1468410395, COSV60523635; called by muse, mutect2, varscan2
- NAB1 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.941); catalogued as COSV61608617; called by muse, mutect2, varscan2
- NAGK | c.465A>G p.S155= | Splice Region (SNP) | VAF 9/20 reads (45%) | catalogued as COSV54903404; called by muse, mutect2, varscan2
- NALCN | c.515+2T>C p.X172_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | catalogued as COSV51931139; called by muse, mutect2, varscan2
- NAV3 | c.5266G>T p.A1756S | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57075429; called by muse, mutect2, varscan2
- NCCRP1 | c.649del p.R217Efs*48 | Frame Shift Del (DEL) | VAF 50/170 reads (29%) | catalogued as rs756352900; called by mutect2, pindel, varscan2
- NEK8 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs776304834, COSV52044467; called by muse, mutect2, varscan2
- NEK8 | c.1826G>A p.G609D | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as COSV52044476; called by muse, mutect2, varscan2
- NEU2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs753794682, COSV52092505; called by muse, mutect2, varscan2
- NF1 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as rs1555608976, COSV62200586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFRKB | c.2470G>A p.A824T (on ENST00000446488 / NM_001143835.2; = p.A849T on NM_006165.3) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV58757616; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as rs145147241; called by mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NIT1 | c.772_773del p.Q258Vfs*6 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | catalogued as rs749380684; called by pindel, varscan2
- NKIRAS1 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV66248231; called by muse, mutect2, varscan2
- NKX2-1 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61388438; called by muse, mutect2, varscan2
- NLGN3 | c.1597del p.V533Ffs*4 (on ENST00000358741 / NM_181303.2; = p.V513Ffs*4 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/167 reads (31%) | catalogued as COSV62444124; called by mutect2, pindel, varscan2
- NLGN4X | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489895501, COSV52014856; called by muse, mutect2, varscan2
- NMT1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.028); catalogued as rs150418753; called by muse, mutect2, varscan2
- NOA1 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV51736655; called by muse, mutect2, varscan2
- NOS3 | c.1319dup p.C441Lfs*57 | Frame Shift Ins (INS) | VAF 29/116 reads (25%) | catalogued as rs749517498; called by mutect2, varscan2
- NR0B2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs756121300, COSV54259288; called by muse, mutect2, varscan2
- NR4A2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs759305222, COSV59892768; called by muse, mutect2, varscan2
- NR5A1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.82); catalogued as rs774672292, COSV65294842, COSV65295748; called by muse, mutect2, varscan2
- NRIP1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748383151, COSV59656855; called by muse, mutect2, varscan2
- NRXN1 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as rs1389440485, COSV68012549; called by muse, varscan2
- NSD1 | c.6116G>A p.R2039H | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100729646, COSV61775024; called by muse, mutect2, varscan2
- NTM | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV66178146; called by muse, mutect2, varscan2
- NUDCD3 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776014477, COSV58126315, COSV58126688; called by muse, mutect2, varscan2
- NUMA1 | c.5295del p.K1766Rfs*2 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs1207322636, COSV52621264; called by mutect2, pindel, varscan2
- NUP214 | c.6073G>A p.G2025R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372915209; called by muse, varscan2
- NUSAP1 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs1223348107, COSV52970932; called by muse, mutect2, varscan2
- OBSCN | c.22167G>C p.W7389C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs752811858, COSV62299136; called by muse, varscan2
- OR10C1 | c.661C>T p.R221C (on ENST00000622521; = p.R219C on NM_013941.3) | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65822599; called by muse, mutect2, varscan2
- OR10G9 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766298513, COSV66686129; called by muse, mutect2
- OR2A5 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as COSV68738672; called by muse, mutect2, varscan2
- OR2T8 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.223); catalogued as rs1013950019, COSV100178273; called by muse, varscan2
- OR4K17 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59647915; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | catalogued as rs755413956; called by mutect2, varscan2
- OR6C75 | c.599del p.L200* | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs746200712; called by mutect2, varscan2
- OR8H3 | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 138/364 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57908596; called by muse, mutect2, varscan2
- OTUD7B | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs782204756, COSV64915963; called by muse, mutect2, varscan2
- P2RY6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370867718; called by muse, mutect2, varscan2
- PAPPA | c.3590C>T p.T1197I | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60281576; called by muse, mutect2, varscan2
- PARD3 | c.2464G>T p.G822* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV60748654; called by muse, mutect2, varscan2
- PARD3B | c.2863A>G p.R955G (on ENST00000406610 / NM_001302769.2; = p.R886G on NM_057177.7) | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.977); catalogued as COSV62509312; called by muse, mutect2, varscan2
- PCDHA5 | c.1234C>A p.L412M | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65351532; called by muse, mutect2, varscan2
- PCDHGA7 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV53933169; called by muse, mutect2, varscan2
- PCLO | c.15188del p.K5063Rfs*2 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as rs1405726136; called by mutect2, pindel, varscan2
- PCNX2 | c.6253C>T p.P2085S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); catalogued as COSV50794969; called by muse, mutect2, varscan2
- PCOLCE | c.205-2A>G p.X69_splice | Splice Site (SNP) | VAF 38/101 reads (38%) | catalogued as COSV53825333; called by muse, mutect2, varscan2
- PDCD5 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV55678260; called by muse, mutect2, varscan2
- PDE11A | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.041); catalogued as COSV53692421; called by muse, mutect2, varscan2
- PDK3 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64793318; called by muse, mutect2, varscan2
- PERP | c.289_291del p.F97del | In Frame Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs1202551064; called by pindel, varscan2
- PHEX | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV65075078; called by muse, mutect2, varscan2
- PHF20L1 | c.1721del p.K574Rfs*28 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs772333737; called by mutect2, varscan2
- PHF3 | c.3099T>C p.H1033= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as rs200070009; called by muse, mutect2, varscan2
- PHLPP2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757343484, COSV62424079; called by muse, mutect2, varscan2
- PIGG | c.2806G>A p.V936I (on ENST00000453061 / NM_001127178.3; = p.V928I on NM_017733.4) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs921678414, COSV56317620, COSV56321817; called by muse, mutect2, varscan2
- PIGO | c.2354G>C p.G785A | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.699); catalogued as COSV53053424, COSV53055013; called by muse, mutect2, varscan2
- PIK3C2A | c.340del p.T114Hfs*10 | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | catalogued as COSV56402935; called by mutect2, pindel, varscan2
- PITPNM2 | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368519330; called by muse, mutect2
- PKD1L1 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.867); catalogued as COSV56963180; called by muse, mutect2, varscan2
- PKP1 | c.40T>C p.C14R | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV55820859; called by muse, mutect2, varscan2
- PLA2G4D | c.428+1G>A p.X143_splice | Splice Site (SNP) | VAF 30/87 reads (34%) | catalogued as rs1053010908, COSV51820341; called by muse, mutect2, varscan2
- PLCG1 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs758702634, COSV54817793; called by muse, mutect2, varscan2
- PLEC | c.13223C>T p.S4408L (on ENST00000322810 / NM_201380.4; = p.S4298L on NM_000445.5) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV59627850; called by muse, mutect2, varscan2
- PLEC | c.9212C>T p.T3071M (on ENST00000322810 / NM_201380.4; = p.T2961M on NM_000445.5) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs368122904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.9002A>G p.Y3001C (on ENST00000322810 / NM_201380.4; = p.Y2891C on NM_000445.5) | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59627995; called by muse, mutect2, varscan2
- PLEKHG2 | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs143655102; called by muse, varscan2
- PLEKHG5 | c.970A>G p.R324G (on ENST00000400915 / NM_001042663.3; = p.R287G on NM_020631.6) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV61700141; called by muse, mutect2, varscan2
- PLIN4 | c.1882G>A p.V628M (on ENST00000301286; = p.V643M on NM_001367868.2) | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs201957398; called by muse, mutect2, varscan2
- PLK2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57106823; called by muse, varscan2
- PLOD3 | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs746896780, COSV56182492; called by muse, mutect2, varscan2
- PLPPR1 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100883403, COSV66452513; called by muse, mutect2, varscan2
- PNRC1 | c.908G>C p.S303T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV60139520, COSV60140525; called by muse, mutect2, varscan2
- POMT1 | c.1261dup p.L421Pfs*13 | Frame Shift Ins (INS) | VAF 34/128 reads (27%) | catalogued as rs749018170; called by mutect2, pindel, varscan2
- PPAN-P2RY11 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs201061727, COSV53452369; called by muse, mutect2, varscan2
- PPM1K | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV55795597; called by muse, mutect2, varscan2
- PPP1R16B | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55376791; called by muse, mutect2, varscan2
- PPP2R3A | c.735del p.K245Nfs*6 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as rs1204228863; called by mutect2, pindel, varscan2
- PPP4R3A | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1463941060, COSV61504257; called by muse, mutect2, varscan2
- PPP4R3B | c.2178A>C p.K726N (on ENST00000616407 / NM_001122964.3; = p.K641N on NM_020463.4) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV55403939; called by muse, mutect2, varscan2
- PPP4R3B | c.1243_1245del p.L415del | In Frame Del (DEL) | VAF 15/65 reads (23%) | catalogued as rs781656640; called by pindel, varscan2
- PRCC | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV54855902; called by muse, mutect2, varscan2
- PREX1 | c.787T>C p.S263P | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.905); catalogued as COSV64250866; called by muse, mutect2, varscan2
- PRKCG | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1332750340, COSV54726922; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as rs753236928; called by mutect2, varscan2
- PRUNE2 | c.4237C>T p.R1413C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs759365654, COSV100945281, COSV65040724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as COSV99194092; called by mutect2, pindel, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 13/107 reads (12%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTGS1 | c.1444+2T>C p.X482_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as COSV56291376; called by muse, mutect2, varscan2
- PTK2B | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180404480, COSV57754592; called by muse, mutect2, varscan2
- PTK2B | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761635419, COSV57754614; called by muse, mutect2, varscan2
- PTOV1 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV55587513; called by muse, mutect2, varscan2
- PTPN18 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV51558701; called by muse, mutect2, varscan2
- PTPN23 | c.4196C>T p.T1399M | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1206430711, COSV55544132; called by muse, mutect2, varscan2
- PTPRE | c.420+1G>A p.X140_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV54549864; called by muse, mutect2, varscan2
- PTPRM | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.968); catalogued as rs1186057037, COSV59855266, COSV59860563; called by muse, mutect2, varscan2
- PTPRR | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs905718588, COSV51730240; called by muse, mutect2, varscan2
- PTPRT | c.3929A>C p.E1310A | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.869); catalogued as COSV61976145; called by muse, mutect2, varscan2
- PUM3 | c.1728T>A p.C576* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV65896683; called by muse, mutect2, varscan2
- PXDNL | c.3128G>A p.G1043D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV62485934; called by muse, mutect2, varscan2
- PXDNL | c.2413C>T p.H805Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV62485945; called by muse, mutect2, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs755727862; called by mutect2, varscan2
- QRICH2 | c.4817G>A p.R1606Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs763464304, COSV53152683; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2364G>A p.M788I | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV54759448; called by muse, mutect2, varscan2
- RAB3B | c.473-1G>T p.X158_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100862493; called by muse, mutect2, varscan2
- RAD54L2 | c.3841G>A p.V1281M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs754407997, COSV56578179; called by muse, mutect2, varscan2
- RALGAPA1 | c.1826del p.N609Ifs*2 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs748033282; called by mutect2, varscan2
- RALGAPA1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99354771; called by muse, mutect2, varscan2
- RALGAPB | c.2495T>C p.M832T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV53436908; called by muse, mutect2, varscan2
- RANBP9 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50580900; called by muse, mutect2, varscan2
- RAPGEF6 | c.1616A>G p.E539G | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1364057200, COSV57244849; called by muse, varscan2
- RAPGEF6 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57244875; called by muse, varscan2
- RB1CC1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1417103747, COSV50246766; called by muse, mutect2, varscan2
- RBAK | c.1925A>G p.Y642C | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV62331271; called by muse, mutect2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs749563266; called by mutect2, varscan2
- RCC1 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs745611564, COSV65779343; called by muse, mutect2, varscan2
- RELA | c.560-2A>G p.X187_splice | Splice Site (SNP) | VAF 31/75 reads (41%) | catalogued as COSV58014542; called by muse, mutect2, varscan2
- RFX2 | c.260+2T>C p.X87_splice | Splice Site (SNP) | VAF 32/139 reads (23%) | catalogued as rs111454935, COSV57941037; called by muse, mutect2, varscan2
- RGS20 | c.527G>A p.R176Q (on ENST00000297313 / NM_170587.4; = p.R29Q on NM_003702.4) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs761091721, COSV52014370; called by mutect2, varscan2
- RIBC1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs1556893207, COSV51447724; called by muse, mutect2
- RIF1 | c.3357_3359del p.M1119del | In Frame Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs780078472; called by pindel, varscan2
- RIMS2 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs768998207, COSV68477326; called by muse, mutect2, varscan2
- RIMS2 | c.3302G>A p.R1101Q (on ENST00000666250 / NM_001348490.2; = p.R909Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752574736, COSV51674365; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 58/201 reads (29%) | catalogued as rs761874510; called by mutect2, pindel
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF139 | c.1142C>A p.S381Y | Missense Mutation (SNP) | VAF 100/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52679077; called by muse, mutect2, varscan2
- RNF213 | c.11900C>T p.T3967M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as rs1007181374, COSV60395532; called by muse, mutect2, varscan2
- RNF26 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777702624, COSV60990301, COSV60991229; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 87/165 reads (53%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.1559T>C p.L520P | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV60418625; called by muse, mutect2, varscan2
- RNFT2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs764785579, COSV57484822, COSV57489380; called by muse, mutect2, varscan2
- RNGTT | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55649462; called by muse, mutect2, varscan2
- ROCK1 | c.362dup p.W122Lfs*25 | Frame Shift Ins (INS) | VAF 32/85 reads (38%) | catalogued as rs35810558; called by mutect2, pindel, varscan2
- RPA4 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs1384744713, COSV61266930; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPSA | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV100088115; called by muse, mutect2, varscan2
- RRAGB | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs752127127, COSV53329356; called by muse, mutect2, varscan2
- RUFY1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756420861, COSV60159556; called by muse, mutect2, varscan2
- RYR1 | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs555272546, COSV62095227; called by muse, mutect2, varscan2
- RYR3 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs780640652, COSV66783041; called by muse, mutect2, varscan2
- S1PR3 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278036049, COSV63980460; called by muse, mutect2, varscan2
- SACS | c.11624G>A p.R3875H | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs863224916, CM138559, COSV66538706; called by muse, mutect2, varscan2
- SALL4 | c.2129C>T p.T710M | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs761020459, COSV53851667; called by muse, mutect2, varscan2
- SAMD15 | c.1115dup p.N372Kfs*21 | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | catalogued as rs111283439; called by mutect2, varscan2
- SAP130 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.115); catalogued as COSV52095351, COSV52096433; called by muse, mutect2, varscan2
- SCARA5 | c.1435del p.V479* | Frame Shift Del (DEL) | VAF 31/129 reads (24%) | catalogued as rs1246802832; called by mutect2, pindel, varscan2
- SCN9A | c.5258A>G p.N1753S (on ENST00000303354; = p.N1742S on NM_002977.3) | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV57607257; called by muse, mutect2, varscan2
- SCUBE1 | c.2053G>T p.G685C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62611870; called by muse, mutect2, varscan2
- SDCBP2 | c.869C>T p.P290L (on ENST00000339987 / NM_001199784.1; = p.P205L on NM_015685.5) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV60588959; called by muse, mutect2, varscan2
- SDK1 | c.5951C>T p.A1984V | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs751764333, COSV101269399, COSV67355098; called by muse, mutect2, varscan2
- SEC31B | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV64824726; called by muse, mutect2, varscan2
- SEMA3A | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV54867955; called by muse, mutect2, varscan2
- SEMA6A | c.2768A>T p.N923I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV56710868; called by muse, mutect2, varscan2
- SEPTIN9 | c.1184T>A p.V395D (on ENST00000427177 / NM_001113491.2; = p.V377D on NM_006640.4) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV61204076; called by muse, mutect2, varscan2
- SERPINB8 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54639476; called by muse, mutect2, varscan2
- SGMS1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1458198286, COSV62370233; called by muse, mutect2, varscan2
- SGO2 | c.1226del p.K409Rfs*52 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | catalogued as rs753732219; called by mutect2, pindel, varscan2
- SHISA2 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.1); catalogued as COSV60110607; called by muse, mutect2, varscan2
- SHROOM2 | c.2168C>A p.T723N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as COSV66605977; called by muse, mutect2, varscan2
- SIDT2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753300776, COSV54056518; called by muse, mutect2, varscan2
- SINHCAF | c.218del p.N73Tfs*6 | Frame Shift Del (DEL) | VAF 30/42 reads (71%) | catalogued as rs771414532; called by mutect2, varscan2
- SIT1 | c.356G>T p.R119M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV52399834; called by muse, mutect2, varscan2
- SLC14A2 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV54908323; called by muse, mutect2, varscan2
- SLC15A1 | c.1449del p.E485Kfs*7 | Frame Shift Del (DEL) | VAF 39/127 reads (31%) | catalogued as COSV64729883; called by mutect2, pindel, varscan2
- SLC25A26 | c.259A>T p.T87S | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60914396; called by muse, mutect2, varscan2
- SLC27A1 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560594335, COSV53096847; called by muse, mutect2, varscan2
- SLC44A3 | c.1722del p.F574Lfs*4 (on ENST00000271227 / NM_001114106.3; = p.F526Lfs*4 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 52/184 reads (28%) | catalogued as rs752543591, COSV54732637; called by mutect2, pindel, varscan2
- SLC4A4 | c.317del p.P106Lfs*56 (on ENST00000264485 / NM_001098484.3; = p.P62Lfs*56 on NM_003759.4) | Frame Shift Del (DEL) | VAF 39/176 reads (22%) | catalogued as COSV52623790; called by mutect2, pindel, varscan2
- SLC6A14 | c.1241del p.F414Sfs*4 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs1556694514; called by mutect2, varscan2
- SLC6A3 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs376877303; called by muse, mutect2, varscan2
- SLC7A14 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs776182109, COSV51580976; called by muse, mutect2, varscan2
- SLC9C2 | c.1550T>C p.I517T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); catalogued as COSV62945354; called by muse, mutect2, varscan2
- SLIT2 | c.992T>C p.L331P | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56569346; called by muse, mutect2, varscan2
- SMAD2 | c.407A>T p.D136V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV50996932; called by muse, mutect2, varscan2
- SMARCB1 | c.953_955del p.K318del (on ENST00000263121; = p.K364del on NM_003073.5) | In Frame Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs875989800; called by pindel, varscan2
- SMCR8 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764581765, COSV58176809; called by muse, mutect2, varscan2
- SMG6 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.254); catalogued as COSV53966232; called by muse, mutect2, varscan2
- SNAPC4 | c.2519G>A p.S840N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53732542; called by muse, mutect2
- SNRNP48 | c.333T>C p.N111= | Splice Region (SNP) | VAF 22/45 reads (49%) | catalogued as COSV60939234; called by muse, varscan2
- SNX11 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100821723, COSV63658321; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | catalogued as rs768873484; called by mutect2, varscan2
- SORCS1 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV53859873; called by muse, mutect2, varscan2
- SPAG16 | c.136+2T>C p.X46_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV55985023; called by muse, varscan2
- SPANXN1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs376051189, COSV65122290; called by muse, mutect2, varscan2
- SPATA20 | c.1897C>T p.R633C (on ENST00000356488 / NM_001258372.1; = p.R649C on NM_022827.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs755985686, COSV50066383; called by muse, mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 35/115 reads (30%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPIC | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1255286492, COSV54690948; called by muse, mutect2, varscan2
- SPTA1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs765863394, COSV63749606; called by muse, mutect2, varscan2
- SQLE | c.254del p.P85Lfs*25 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs760774524; called by mutect2, pindel, varscan2
- SRD5A3 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.28); catalogued as rs549620113, COSV51711821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SREBF2 | c.205A>G p.S69G | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63330495; called by mutect2, varscan2
- STAB1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs532380871, COSV58735171; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | catalogued as rs752994755; called by mutect2, varscan2
- STAT1 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV63115865; called by muse, mutect2, varscan2
- STK26 | c.701del p.N234Tfs*22 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as COSV100688844; called by mutect2, pindel, varscan2
- STYXL2 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs549179166, COSV54804341; called by muse, mutect2, varscan2
- SULF1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.258); catalogued as rs765825581, COSV52679534; called by muse, mutect2, varscan2
- SYNE1 | c.17680C>T p.Q5894* (on ENST00000367255 / NM_182961.4; = p.Q5823* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV54962746; called by muse, mutect2, varscan2
- SYNE1 | c.16280G>T p.S5427I (on ENST00000367255 / NM_182961.4; = p.S5356I on NM_033071.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV54962795; called by muse, mutect2, varscan2
- SYT7 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.36); catalogued as rs1384951420, COSV55655277; called by muse, mutect2, varscan2
- SYTL5 | c.1033A>G p.S345G | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV52900289; called by muse, mutect2, varscan2
- TAF9B | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV59371179; called by muse, mutect2, varscan2
- TANK | c.1234del p.D412Ifs*27 | Frame Shift Del (DEL) | VAF 35/120 reads (29%) | catalogued as COSV52043878; called by mutect2, pindel, varscan2
- TAS1R1 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59839697; called by muse, mutect2, varscan2
- TAT | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750638957, COSV63532687; called by muse, mutect2, varscan2
- TBC1D4 | c.3542T>C p.V1181A | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66488853; called by muse, mutect2, varscan2
- TBC1D8 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs774137261, COSV65211744; called by muse, mutect2, varscan2
- TBL1X | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as rs1267475619, COSV54278813; called by muse, mutect2, varscan2
- TCF3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs199628190, COSV53647745; called by muse, mutect2, varscan2
- TCP11 | c.826C>T p.P276S (on ENST00000512012; = p.P214S on NM_018679.5) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV55133395; called by muse, mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 118/182 reads (65%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM4 | c.2836A>G p.N946D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53623359; called by muse, mutect2, varscan2
- TENT2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV57136616; called by muse, mutect2, varscan2
- TERF2 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs376057884; called by muse, mutect2, varscan2
- TERT | c.3150G>T p.K1050N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as CM157418, COSV57211267; called by muse, mutect2, varscan2
- TET3 | c.2962A>G p.M988V | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69641465; called by muse, mutect2, varscan2
- TGFB1I1 | c.199C>T p.R67W (on ENST00000394863 / NM_001042454.3; = p.R50W on NM_015927.4) | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV62357779; called by muse, mutect2, varscan2
- TIMM44 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV54491067; called by muse, mutect2, varscan2
- TMCC2 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777776134, COSV58002629; called by muse, mutect2, varscan2
- TMEM161A | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772353830, COSV50776477; called by muse, mutect2
- TMEM175 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs368224007; called by muse, mutect2, varscan2
- TMEM184B | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs370041072; called by muse, mutect2, varscan2
- TMEM263 | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV55013927; called by muse, mutect2, varscan2
- TMEM44 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs141093359; called by muse, mutect2, varscan2
- TMEM47 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52064366, COSV52067203; called by muse, mutect2, varscan2
- TMPRSS4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs536140913, COSV71108760; called by muse, mutect2, varscan2
- TMTC1 | c.1556C>T p.A519V (on ENST00000539277 / NM_001193451.2; = p.A411V on NM_175861.3) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1359298899, COSV55479735; called by muse, mutect2, varscan2
- TMTC3 | c.2274dup p.C759Mfs*3 | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs1304750530; called by mutect2, varscan2
- TNFAIP1 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV50228345; called by muse, mutect2, varscan2
- TNFRSF1A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV50599639; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 51/130 reads (39%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TNNI2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.299); catalogued as COSV53289421; called by mutect2, varscan2
- TNS2 | c.1977del p.K660Nfs*96 (on ENST00000314250 / NM_170754.4; = p.K670Nfs*96 on NM_015319.2) | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs1379053061; called by mutect2, pindel, varscan2
- TNS3 | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as rs758690826, COSV60789997; called by muse, mutect2, varscan2
- TRDMT1 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV58319017; called by muse, mutect2, varscan2
- TREX2 | c.223C>A p.L75I (on ENST00000334497; = p.L32I on NM_080701.3) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57848489; called by muse, mutect2
- TRIM50 | c.596del p.G199Vfs*61 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as rs1554544598; called by mutect2, pindel, varscan2
- TRIM58 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs777618771, COSV63569168; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 28/108 reads (26%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIM61 | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61418006; called by muse, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIOBP | c.5087C>A p.P1696H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as rs1187570589, COSV60376498; called by muse, mutect2, varscan2
- TRIP10 | c.1157T>C p.V386A (on ENST00000313244 / NM_001288962.2; = p.V330A on NM_004240.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.93); catalogued as COSV57571114; called by muse, mutect2
- TRIP10 | c.1479dup p.A494Rfs*2 (on ENST00000313244 / NM_001288962.2; = p.A438Rfs*2 on NM_004240.4) | Frame Shift Ins (INS) | VAF 26/60 reads (43%) | catalogued as rs762545513; called by mutect2, varscan2
- TRMT12 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60776862; called by muse, mutect2, varscan2
- TRPA1 | c.1414A>G p.T472A | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV51559933; called by muse, mutect2, varscan2
- TRPM4 | c.734del p.G245Afs*33 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as COSV53267877; called by mutect2, pindel, varscan2
- TRPS1 | c.2771A>G p.Q924R (on ENST00000220888 / NM_001330599.2; = p.Q937R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55236944; called by muse, mutect2, varscan2
- TRPT1 | c.329T>C p.V110A (on ENST00000317459 / NM_001160393.1; = p.V61A on NM_031472.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV54173096; called by muse, mutect2, varscan2
- TRPV3 | c.1406T>C p.I469T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56790690; called by muse, mutect2
- TSC22D4 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs143908452; called by muse, mutect2, varscan2
- TSPAN12 | c.616T>G p.C206G | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56079219; called by muse, mutect2, varscan2
- TTN | c.96716A>G p.E32239G (on ENST00000591111; = p.E24815G on NM_003319.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | PolyPhen probably damaging (0.999); catalogued as COSV60002171; called by muse, mutect2, varscan2
- TTN | c.70244C>T p.A23415V (on ENST00000591111; = p.A15991V on NM_003319.4) | Missense Mutation (SNP) | VAF 52/187 reads (28%) | PolyPhen probably damaging (0.997); catalogued as COSV60002202; called by muse, mutect2, varscan2
- TTN | c.32797G>T p.E10933* (on ENST00000591111; = p.E10006* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV59875855, COSV60002238; called by muse, mutect2, varscan2
- TTN | c.23388A>C p.K7796N (on ENST00000591111; = p.K6869N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | PolyPhen benign (0.202); catalogued as COSV60002248; called by muse, mutect2, varscan2
- TUBB8 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs559882106, COSV59115129; called by muse, mutect2, varscan2
- TXNDC11 | c.2201G>A p.R734Q (on ENST00000356957 / NM_001303447.2; = p.R707Q on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.479); catalogued as rs372009950; called by muse, mutect2, varscan2
- UAP1L1 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV64306424; called by muse, mutect2, varscan2
- UBA2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55828092; called by muse, mutect2, varscan2
- UBXN6 | c.654dup p.E219* | Frame Shift Ins (INS) | VAF 17/47 reads (36%) | catalogued as rs765606534; called by mutect2, pindel, varscan2
- UGT1A4 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs369434904; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UPP2 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50046729; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | catalogued as rs747493460; called by mutect2, varscan2
- USP9X | c.5041C>T p.R1681C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61068480; called by muse, mutect2, varscan2
- UTP14C | c.1425del p.A476Qfs*37 | Frame Shift Del (DEL) | VAF 53/200 reads (27%) | catalogued as rs1414730494; called by mutect2, pindel, varscan2
- UXT | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs1457961356, COSV60039202; called by muse, mutect2, varscan2
- VCP | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201431036, COSV62720296, COSV62721928; called by muse, mutect2, varscan2
- VPS13A | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62428496; called by muse, mutect2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13B | c.5858C>A p.P1953H | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV62139369; called by muse, mutect2, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | catalogued as rs756221452; called by mutect2, varscan2
- VSIR | c.856del p.L286Cfs*51 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs752718137, COSV56484595; called by mutect2, pindel, varscan2
- WDFY3 | c.3724G>A p.V1242M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV55699289; called by muse, mutect2, varscan2
- WDR36 | c.1866A>C p.Q622H | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV72605157; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR90 | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53468758; called by muse, mutect2, varscan2
- WFDC6 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60548512; called by muse, mutect2, varscan2
- WNK1 | c.3800G>T p.R1267L (on ENST00000315939 / NM_018979.4; = p.R1020L on NM_014823.3) | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60025904, COSV60031315; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- WNT7B | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768081658, COSV59749459; called by muse, mutect2, varscan2
- XYLT2 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs760929594, COSV50017537; called by muse, mutect2, varscan2
- YY2 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV63411201; called by muse, mutect2, varscan2
- ZAN | c.5385G>T p.Q1795H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV61808085; called by muse, mutect2, varscan2
- ZBTB39 | c.1631G>A p.S544N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55627770, COSV55629064; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDHHC16 | c.122A>T p.Y41F | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV61749047; called by muse, mutect2, varscan2
- ZFYVE28 | c.1469G>A p.G490D | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); catalogued as rs967368316, COSV52110230; called by muse, mutect2, varscan2
- ZIM2 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs774278374, COSV55629223, COSV55629804; called by muse, mutect2, varscan2
- ZMAT1 | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV65658291; called by muse, mutect2
- ZNF100 | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.062); catalogued as COSV64168025; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 62/182 reads (34%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF221 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.993); catalogued as COSV52109020; called by muse, mutect2, varscan2
- ZNF236 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs200466079, COSV53482197, COSV53486617; called by muse, mutect2, varscan2
- ZNF335 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1426169751, COSV100532528, COSV59817318; called by muse, mutect2, varscan2
- ZNF354A | c.553dup p.T185Nfs*6 | Frame Shift Ins (INS) | VAF 49/183 reads (27%) | catalogued as rs1164748265; called by mutect2, pindel, varscan2
- ZNF516 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs572186968, COSV71586924; called by muse, mutect2, varscan2
- ZNF548 | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV60240806; called by muse, mutect2, varscan2
- ZNF551 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV56592396; called by muse, mutect2, varscan2
- ZNF552 | c.1075A>C p.K359Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66971608; called by muse, mutect2, varscan2
- ZNF624 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV60939816; called by muse, mutect2, varscan2
- ZNF630 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV52096065; called by muse, mutect2, varscan2
- ZNF646 | c.3682G>A p.G1228S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748083294, COSV54923871; called by muse, mutect2, varscan2
- ZNF875 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV60991010; called by muse, mutect2, varscan2
- ZSCAN16 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs767744414, COSV61258557; called by muse, mutect2, varscan2
- ZZEF1 | c.4015G>A p.A1339T | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs184809048, COSV67556254; called by muse, mutect2, varscan2
- AC098582.1 | c.3047_3049del p.L1016del | In Frame Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.383dup p.L128Ffs*15 | Frame Shift Ins (INS) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- ADD3 | c.2101_2102del p.K701Gfs*4 (on ENST00000356080 / NM_001320591.2; = p.K669Gfs*4 on NM_001121.4) | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by pindel, varscan2
- AKAP11 | c.1622del p.N541Ifs*4 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- ALG10 | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 42/145 reads (29%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, varscan2
- ARHGAP5 | c.2828del p.N943Ifs*2 | Frame Shift Del (DEL) | VAF 25/59 reads (42%) | called by mutect2, varscan2
- ARID1B | c.3210_3211del p.G1071Lfs*33 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by pindel, varscan2
- ATG2B | c.4796del p.G1599Efs*9 | Frame Shift Del (DEL) | VAF 33/101 reads (33%) | called by pindel, varscan2
- ATP8B4 | c.1169del p.F390Sfs*13 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- C2orf42 | c.1230del p.K410Nfs*38 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- CACNA2D3 | c.663del p.F221Lfs*40 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- CD86 | c.807del p.K269Nfs*63 (on ENST00000330540 / NM_175862.5; = p.K263Nfs*63 on NM_006889.4) | Frame Shift Del (DEL) | VAF 42/186 reads (23%) | called by mutect2, pindel, varscan2
- CEP162 | c.405del p.F135Lfs*8 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- CEP57 | c.1420del p.R474Gfs*8 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4609C>G p.L1537V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CGB7 | c.25_27dup p.L13dup | In Frame Ins (INS) | VAF 26/94 reads (28%) | called by mutect2, varscan2
- CLSPN | c.2158_2159del p.S720Ifs*9 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by pindel, varscan2
- CTNNA2 | c.2128_2130del p.D710del | In Frame Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- CTNND1 | c.566del p.G189Dfs*46 | Frame Shift Del (DEL) | VAF 59/243 reads (24%) | called by mutect2, pindel, varscan2
- CUL5 | c.1694del p.N565Ifs*18 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | called by mutect2, varscan2
- CXorf56 | c.343del p.T115Rfs*14 (on ENST00000536133 / NM_001170570.2; = p.T129Rfs*14 on NM_022101.4) | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- CYLC2 | c.630del p.G211Efs*22 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- CYP8B1 | c.315del p.K105Nfs*4 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- DBF4 | c.74del p.N25Tfs*5 | Frame Shift Del (DEL) | VAF 70/181 reads (39%) | called by mutect2, pindel, varscan2
- DENND4C | c.4121_4123del p.S1374del (on ENST00000434457 / NM_001330640.2; = p.S1325del on NM_017925.7) | In Frame Del (DEL) | VAF 16/60 reads (27%) | called by pindel, varscan2
- DGKG | c.1413del p.P472Lfs*5 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- DLST | c.527del p.P176Lfs*27 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
360 further variants in this file (94 protein-altering or splice-affecting, 234 silent, 32 other) are not listed here.
